Surgical pathology report (de-identified scan), TCGA case TCGA-23-2084, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-2084-01A (Primary Tumor).

[page 1 of 6]
PATHOLOGY REPORT

PATH

A/S:

Rec:

Col:

Pathologist:
Assistant:
Attending MD:
Ordering MD:
Copies To:

TCGA-23-2084

=====

DIAGNOSIS:

- 1-5: "RIGHT IP NODE", EXCISION, OMENTUM, PARTIAL OMENTECTOMY, OMENTUM, BIOPSY, ROUND LIGAMENT, BIOPSY, CUL DE SAC TUMOR", EXCISION:
-Metastatic high-grade serous carcinoma extensively involving soft tissues and lymphovascular spaces (regional lymphatics) in all five involved sites
6. FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY:
-Right ovarian serous carcinoma, grade III (see comment)
-Ovary (ovarian parenchyma) is nearly totally replaced by carcinoma
-Serosal surface of ovary is involved by tumor
-Lymphovascular space invasion by tumor in ovary is extensive
-Fallopian tube with secondary involvement of serosa, wall and lymphatics, including mucosal lymphatics by serous carcinoma
-Adnexal soft tissues/ligaments and regional (adnexal) lymphovascular spaces are also extensive involved by serous carcinoma
-Ovary also shows follicular cyst
7. FALLOPIAN TUBE AND OVARY, LEFT SALPINGO-OOPHORECTOMY:
-Left ovary with serous carcinoma, grade III (see comment)
-Ovary (ovarian parenchyma) is subtotally replaced by carcinoma
-Serosal surface of ovary is involved by tumor
-Lymphovascular space invasion by tumor within ovary is extensive
-Fallopian tube with intramucosal/intraepithelial high-grade serous carcinoma, serous carcinoma within tubal lymphatics, and involving serosal surface of fallopian tube
-Serous carcinoma also involves adnexal soft tissue/ligament and lymphovascular spaces within adnexal soft tissues
-Ovary also shows a luteinized follicular cyst, a mesothelial cyst and stromal edema
8. [MESENTERY], "SIGMOID TUMOR", EXCISION:
-Metastatic serous carcinoma virtually replacing soft tissues and extensively involving regional lymphovascular spaces
9. LYMPH NODE, LEFT PELVIC, EXCISION:
-One lymph node showing near total replacement by metastatic serous carcinoma (1/1)
-Metastatic serous carcinoma is also present in regional lymphatic and perinodal fat
10. MESENTERY, "MESENTERIC TUMOR", EXCISION:

[page 2 of 6]
- Metastatic serous carcinoma extensive involving mesenteric fat and regional lymphovascular spaces
- 11. [MESENTERY/SEROSA], JEJUNUM "TUMOR", EXCISION:
- Metastatic serous carcinoma extensively involving soft tissues (mesenteric fat) and regional lymphovascular spaces
- 12. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:
- Serous carcinoma, high-grade (see comment) involving:
- Lymphovascular spaces (regional lymphatics) within endometrial mucosa, uterine wall, including deep aspect of wall, and subserosal lymphatics of uterus
- Areas of endometrial mucosal involvement by serous carcinoma, favor metastatic, with intramucosal extension from involved lymphatics
- Patchy foci of myometrial invasion by serous carcinoma, including in deep aspect of uterine wall, probably via extension from involved lymphatics
- Cervix (ectocervix and endocervix) with extensive lymphovascular space invasion by serous carcinoma including lymphatics deep within wall, intramucosal lymphatics and lymphatics near external surface
- Lymphovascular space invasion by serous carcinoma within cervix extends very close to (within less than 1 mm of the surgical margin)
- Other findings include:
- Disordered proliferative to focally minimally hyperplastic endometrium (latter simple type without significant atypia) with focal superimposed secretory-like changes and foci of ciliated epithelial metaplasia
- Reactive lymphoid aggregates within endometrial mucosa
- Four small uterine leiomyomas, one of which exhibits focal "epithelioid" features
- Adenomyosis
- Uterine serosal adhesions
- Microglandular endocervical hyperplasia and foci of mild macroglandular endocervical hyperplasia without significant cellular atypia
- Foci of ciliated metaplasia of endocervical epithelium
- Endocervical nabothian cysts
- Cervix with minimal (focal) superficial mucosal erosions, acute and chronic inflammation, reserve cell hyperplasia, squamous metaplasia, and reactive epithelial changes
- Focal parakeratosis of ectocervical squamous epithelium
- 13. ILEUM (TERMINAL), RIGHT COLON, MESENTERY, AND REGIONAL LYMPH NODES, SEGMENTAL RESECTION:
- Metastatic serous carcinoma, multifocal, involving:
- A 4 cm diameter area of the cecum; tumor involvement of cecum involves the serosa, subserosa, full thickness of muscular wall, submucosa and focally the mucosa
- Second 4.5 cm tumor mass involving distal right colon; involvement of distal right colon is also transmural with involvement of serosa, subserosa, full thickness of muscular wall, submucosa and focally the mucosa
- Regional lymphovascular spaces invasion by tumor in vicinity of cecal and distal right colon masses, as well as elsewhere in colon and mesentery/pericolic fat is extensive
- Multiple other nodular and plaque like deposits of metastatic tumor ranging from microscopic to about 1 cm in maximum dimension are present within other segments of the right colon, the small intestine, and pericolic/mesenteric fat
- Metastatic carcinoma is present about 1 cm from the proximal (ileal) margin of resection
- Bulk tumor (nodular aggregate of carcinoma) is present about 2 cm from the distal (colonic) margin of resection
- Metastatic carcinoma within lymphatics is present about 3

[page 3 of 6]
mm from the distal surgical margin
-Four of four mesenteric/pericolic/small intestinal lymph nodes are positive for metastatic carcinoma (4/4); the involved lymph nodes are subtotally replaced by tumor
-Tumor is also present in perinodal lymphatic and perinodal fat

COMMENT:

This high-grade primary ovarian (bilateral ovarian) serous carcinoma exhibits predominantly solid growth (with a "undifferentiated"-like appearance), and also exhibits papillary growth and focal glandular growth. Both fallopian tubes exhibit secondary involvement by serous carcinoma. In addition, the left fallopian tube shows an area of intraepithelial/intramucosal carcinoma, which may be primary to that site. Intraluminal aggregates of serous carcinoma are also present in the left fallopian tube. There is extensive lymphovascular space invasion by carcinoma in all involved sites, including the uterus and cervix. Within the uterus, the endometrial mucosal involvement by serous carcinoma is predominantly within lymphatic spaces. There are, however, a few small foci of mucosal involvement extrinsic to lymphatics. While the latter might represent primary uterine papillary serous carcinoma, the alternate possibility that the endometrial deposits of tumor within the uterus represent secondary extension into the mucosa from involved lymphatic spaces is favored.

Findings in an additional routinely stained sections have been incorporated in the final diagnosis.

=====

HISTORY: Ovarian carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1. RIGHT I P NODE

Labeled with the patient's name, designated right IP node" and received in formalin is an irregular 1.9 x 1.6 x 1.2 cm firm, white-tan nodular aggregate of tumor.

Representative section.

A: Tumor - 1

2. OMENTUM

Labeled with the patient's name, designated "omentum", received fresh in the Operating Room for intraoperative frozen section diagnosis is a 23 x 12 x 1.3 cm portion of lobulated yellow omental fat which is extensively involved by nodular and plaque like aggregates of firm, tan-white tumor, some of the tumor aggregates are confluent. The largest individual tumor aggregate measures about 3 cm in greatest dimension. Two representative sections of omental tumor are frozen and sectioned for intraoperative diagnosis. The remaining frozen tissue and the rest of the specimen are then fixed in formalin.

Representative sections.

B: Remnant of frozen section (omentum tumor) - 2

C: Omental tumor - 1

3. OMENTUM BIOPSY

Labeled with the patient's name, designated "omentum biopsy" and received in formalin is an irregular 4 x 4 x 0.7 cm portion of yellow omental fat, which is partially replaced by nodular and plaque like aggregates of firm, tan-white tumor, measuring up to 1.2 cm in greatest dimensions.

Representative sections.

[page 4 of 6]
D: Omentum with tumor - 1

4. ROUND LIGAMENT

Labeled with the patient's name, designated "round ligament" and received in formalin are two irregular aggregates of firm, tan-white tumor each with a small amount of attached uninvolved yellow-tan focally hemorrhagic fibroadipose tissue.

Representative sections.

E: Tumor - 2

5. CUL-DE-SAC TUMOR

Labeled with the patient's name, designated "cul de sac tumor" and received in formalin is a 2.7 x 2.2 x 1 cm aggregate of multiple irregularly shaped fragments of firm, tan-white tumor, some of which have a small amount of attached uninvolved hemorrhagic red-tan soft tissue.

Representative sections.

F: Tumor - 2

6. RIGHT TUBE AND OVARY

Labeled with the patient's name, designated "right tube and ovary", received fresh in the Operating Room and subsequently fixed in formalin, is a salpingo-oophorectomy specimen including an entire ovary, and adjacent fallopian tube, and adjacent/intervening adnexal soft tissues. The ovary is 3.3 x 2.9 x 2.6 cm and has a lobulated yellow-tan focally nodular external surface with small nodular and plaque like aggregates of serosal tumor. Cut surfaces of the ovary reveal near total replacement by firm, variegated tan-white-yellow tumor. There is minimal residual uninvolved ovarian parenchyma, a small 0.3 cm diameter fluid-filled cyst is also noted in the ovary. The fallopian tube, complete with fimbriae at one end is about 6.2 cm long and has an average cross sectional diameter of about 0.7 cm. The serosal surface of the fallopian tube, particularly near the fimbriated end is distorted by firm, small nodular and plaque like aggregates of white-tan tumor. The adnexal soft tissues also are involved by similar-appearing firm, tan-white tumor aggregate, measuring up to about 1 cm in diameter. Cross sections of the fallopian tube reveal a central patent lumen, about 0.3 cm in diameter, and a 0.2 cm average wall thickness.

Representative sections.

G: Fallopian tube and mesosalpinx - 2

H-K: Ovary - 1

7. LEFT TUBE AND OVARY

Labeled with the patient's name, designated "left tube and ovary" and received in formalin is a salpingo-oophorectomy specimen including the entire ovary, fallopian tube, and ligamentous adnexal soft tissues. The ovary is 3.9 x 2.9 x 1.7 cm and has a lobulated tan external surface. The serosal surface of the ovary is distorted by nodular and plaque-like aggregates of firm, tan-white tumor, measuring up to about 0.8 cm in diameter. Cut sections of the ovary reveal subtotal replacement by firm, tan-white tumor. There is a small amount of intervening edematous appearing uninvolved ovarian parenchyma and an amber 1.2 cm diameter cyst with a smooth lining and a 0.1 cm wall thickness. The fallopian tube, complete with fimbria at one end is 6.3 cm long and has an average cross sectional diameter of about 0.5 cm. The serosal surface of the fallopian tube is pink-tan and shows tiny foci, up to about 0.3 cm in diameter of nodular to plaque like aggregates of firm, tan-white tumor. Cross sections of the fallopian tube reveal a central patent lumen, about 0.2 cm in diameter and a 0.1 cm average wall thickness. The adjacent ligamentous paratubal and paraovarian soft tissues are also partially replaced by nodular to plaque like aggregates of similar-appearing firm, tan-white tumor, measuring up to about 0.5 cm in diameter.

Representative sections.

[page 5 of 6]
L: Fallopian tube and mesosalpinx - 2
M-O: Ovary with tumor - 1 each
P: Ovary with tumor and cyst - 2

8. SIGMOID TUMOR

Labeled with the patient's name, designated "sigmoid tumor" and received in formalin is a 2.5 x 1.5 x 0.5 cm aggregate of several irregularly shaped fragments of firm, tan-white tumor, ranging from about 0.3 to 1.2 cm in greatest dimension.

Representative sections.

Q: Tumor - 4

9. LEFT PELVIC NODE

Labeled with the patient's name, designated "left pelvic node" and received in formalin is a 2.5 x 1.4 x 0.8 cm lymph node with scant attached yellow fat. Cut sections of the lymph node reveal near total replacement by firm, white-tan metastatic tumor.

There is total replacement of lymphoid parenchyma by white firm
Representative section.

R: One lymph node - 1

10. MESENTERIC TUMOR

Labeled with the patient's name, designated "mesenteric tumor" and received in formalin is a 2 x 1.5 x 0.3 cm aggregate of several fragments of yellow-tan fibroadipose tissue which are subtotally to near totally replaced by firm, tan-white tumor

Entirely submitted.

S: Mesenteric tumor - multiple

11. JEJUNUM TUMOR

Labeled with the patient's name, designated "jejunum tumor" and received in formalin are several irregular to nodular aggregates of firm, tan-white tumor, some of which have a small amount of attached uninvolved yellow adipose tissue. The individual tumor nodules range from about 0.5 to 1.5 cm in greatest dimensions.

Representative sections.

T: Jejunal tumor - multiple

12. UTERUS

Labeled with the patient's name, designated "uterus" and received in formalin is a 190 gram total hysterectomy specimen. The uterine corpus is symmetric, measuring 5.8 cm superior to inferior, 5.6 cm cornu to cornu, and 4.9 cm anterior to posterior. The serosa is tan-red and roughened with abundant tumor studding. The cervix has a length of 4.2 cm and a diameter of 4.4 cm. There is a 1.1 cm slit-like patent os. The ectocervical mucosa is pink-white and smooth, without obvious lesions. The transformation zone is distinct. The endocervical canal is 2.1 cm in length and is tan and rugose. The endometrial cavity is 4.5 cm in length, 3.5 cm in width, and is lined by a soft red-tan, smooth endometrium with a thickness of 0.3 cm. The endometrium is grossly unremarkable. The myometrium is 3.2 cm in maximum thickness. There are two subserosal and two intramural sharply circumscribed, firm, whorled, tan-white spherical leiomyomas, ranging from 0.3 to 2.5 cm in greatest dimension. On sectioning the cut surfaces are firm, tan-white and whorled without areas of hemorrhage, necrosis, or calcifications. The myometrium is otherwise grossly unremarkable.

Representative sections.

U: Leiomyomas - 4

V: Serosal tumor deposits - 3

W: Anterior uterine corpus - 1

X: Posterior uterine corpus - 1

Y: Anterior cervix-1

Z: Posterior cervix-1

[page 6 of 6]
ADDITIONAL REPRESENTATIVE SECTIONS [REDACTED]

G2: Uterine fundus - 1

H2: Anterior uterine corpus - 1

I2: Anterior lower uterine segment - 1

J2: Posterior uterine corpus - 1

KK: Posterior lower uterine corpus and lower uterine segment - 1

13. TERMINAL ILEUM AND RIGHT COLON

Labeled with the patient's name, designated "terminal ileum and right colon" received in the fresh state in the Operating Room for intra-operative gross consultation and subsequently fixed in formalin is a segment of right colon, 20.3 cm long and 6.5 cm in average circumference, with 27.7 cm of attached small bowel that is 4.9 cm in average circumference. There is moderate pericolic fat and mesenteric fat. Within the adipose tissue are multiple tumor nodules. No appendix is identified grossly. The serosa is tan-red and dull with multiple areas of serosal tumor studding. On opening the bowel contains minimal fecal material. There are two areas of mucosal protrusion, one is 4.0 cm in greatest dimension in the cecum, and the other it is 4.5 cm in greatest dimension and is 2.5 cm from the distal margin. These masses are extending in word from the mesentery and secondarily invade the bowel wall.

Representative sections.

A2: Proximal margin-1

B2: Distal margin-1

C2: Cecal mass-1

D2: Distal mass-1

E2-F2: Mesenteric nodules/lymph nodes?-2 each

[REDACTED]
OPERATIVE CONSULT (FROZEN):

[REDACTED] OMENTUM, PARTIAL OMENTECTOMY:

- Poorly differentiated/undifferentiated carcinoma, favor mullerian-derived

OPERATIVE CONSULT (GROSS):

[REDACTED] TERMINAL ILEUM AND RIGHT COLON:

- Portion of tumor within mesentery, submitted for clonogenic assays

Special Studies: Clonogenic assay; inhibin (P), additional H&E-stained section (L)

See Also [REDACTED]
[REDACTED]
[REDACTED]

I, [REDACTED], the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.
[REDACTED]

Source: NCI Genomic Data Commons file d673ad0f-57a8-4630-9844-56422b4dce8d (TCGA-23-2084.00FD3D04-B48E-434E-8D25-0F0949E796CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).